Surgical pathology report (de-identified scan), TCGA case TCGA-06-0155, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0155-01B (Primary Tumor).

TC6A-06-0155

PATHOLOGICAL DIAGNOSIS:

BRAIN BIOPSY (FRONTAL LOBE): GLIOBLASTOMA MULTIFORME.

MIB-1 LABELLING INDEX

Operation/Specimen: Frontal brain tumor.

Clinical History and Pre-Op Dx: None provided.

GROSS PATHOLOGY:

SPECIMEN: Frontal brain tumor.

FIXATIVE: Formalin.

GENERAL: A 5.0 x 4.0 x 2.0 cm., approximately 11 gm., aggregate of a few irregularly-shaped fragments of tan to gray-tan cerebriform tissue.

SECTIONS: 1-3 - representative.

MICROSCOPIC: Sections show a high grade astrocytoma with large areas of coagulation necrosis, prominent vasculo-endothelial hyperplasia, hypercellularity and nuclear pleomorphism.

ADDENDUM MICROSCOPIC: MIB-2 labelling index of the tumor cells is about 30%.

Source: NCI Genomic Data Commons file 7c7447ef-9391-4666-8ce3-b042abb739cc (TCGA-06-0155.2C5637E2-AC9D-4F08-B684-1A8A57842CA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).